Somatic mutation profile of tumor specimen MP2PRT-PASRGI-TBP1-A (aliquot MP2PRT-PASRGI-TBP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASRGI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,328 days).
Specimen MP2PRT-PASRGI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6076a09-95d4-4558-8a69-46ba7aaae1f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRGI-NM1-B (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRGI-NM1-B-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/051c5168-3f44-4e18-8a81-8e6f592325b1

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 155/366 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CETN1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 139/591 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs775173037, COSV59121801; called by muse, mutect2, varscan2
- CHD3 | c.4825C>T p.R1609W | Missense Mutation (SNP) | VAF 164/601 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.249); catalogued as rs774463931; called by muse, mutect2, varscan2
- CYP2E1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 128/439 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as rs1354838426, COSV99429132; called by muse, mutect2, varscan2
- DOCK9 | c.889G>A p.E297K (on ENST00000376460 / NM_001366676.2; = p.E298K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs1229729407, COSV59638620; called by muse, mutect2, varscan2
- F13B | c.1886G>T p.G629V | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1344077086, COSV66373592; called by muse, mutect2, varscan2
- HYDIN | c.5272G>A p.A1758T | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs540135229, COSV59261703; called by muse, varscan2
- LBP | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs143797991; called by muse, mutect2, varscan2
- MYO1B | c.2977G>A p.V993M (on ENST00000304164; = p.V935M on NM_012223.5) | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762023617, COSV58428035; called by muse, mutect2, varscan2
- OPCML | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59409764, COSV59419626; called by muse, mutect2, varscan2
- PDZRN4 | c.2800G>A p.E934K (on ENST00000402685 / NM_001164595.2; = p.E676K on NM_013377.4) | Missense Mutation (SNP) | VAF 122/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54199851; called by muse, mutect2, varscan2
- RAPH1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs756936403; called by muse, mutect2, varscan2
- RYR3 | c.7497C>A p.C2499* (on ENST00000389232; = p.C2500* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 97/262 reads (37%) | catalogued as COSV66776368; called by muse, mutect2, varscan2
- SSTR5 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 218/579 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753849011; called by muse, mutect2, varscan2
- ZNF354C | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs369251328, COSV100203888; called by muse, mutect2, varscan2
- ACTRT1 | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 165/722 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ATOH7 | c.53dup p.C19Vfs*56 | Frame Shift Ins (INS) | VAF 119/489 reads (24%) | called by mutect2, pindel, varscan2
- C6 | c.60A>T p.Q20H | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC19A | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CSRNP1 | c.1014dup p.M339Hfs*4 | Frame Shift Ins (INS) | VAF 132/458 reads (29%) | called by mutect2, pindel, varscan2
- HEATR1 | c.1500T>A p.N500K | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NDFIP1 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIPOR3 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 188/268 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC25A10 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYCP2L | c.608A>T p.K203I | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TMEM87A | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VGLL2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 273/1052 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC166 | c.243C>T p.S81= | Silent (SNP) | VAF 258/1235 reads (21%) | catalogued as rs1260241034; called by muse, mutect2, varscan2
- LDB3 | c.1956C>T p.D652= | Silent (SNP) | VAF 104/452 reads (23%) | catalogued as rs139213290; ClinVar: benign / likely benign; called by mutect2, varscan2
- MAPK4 | c.345G>T p.L115= | Silent (SNP) | VAF 161/628 reads (26%) | called by muse, mutect2, varscan2
- MARCO | c.453C>T p.G151= | Silent (SNP) | VAF 164/442 reads (37%) | catalogued as rs772799871, COSV59056464; called by muse, mutect2, varscan2
- PIK3R6 | c.1482G>A p.T494= | Silent (SNP) | VAF 59/287 reads (21%) | catalogued as rs372736608; called by muse, mutect2, varscan2
- TSPYL5 | c.90C>T p.D30= | Silent (SNP) | VAF 177/946 reads (19%) | catalogued as COSV100439199; called by muse, mutect2, varscan2
